Somatic mutation profile of tumor specimen MMRF_2701_1_BM_CD138pos (aliquot MMRF_2701_1_BM_CD138pos_T1_KHS5U_L14839) from MMRF case MMRF_2701, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.2 years (22,728 days).
Specimen MMRF_2701_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ae8aa62-fff8-4110-9a41-7a76dac24a03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2701_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2701_1_PB_WBC_C2_KHS5U_L14840; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3f392d9-c105-4e18-801b-c15b6a82d757

The open-access MAF lists 110 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 22, Intron 21, Silent 10, 5'Flank 4, Frame Shift Del 3, RNA 2, 5'UTR 2, 3'Flank 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV55972705; called by muse, mutect2, varscan2
- CBARP | c.1091C>T p.T364M (on ENST00000382477; = p.T344M on NM_152769.3) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759376967, COSV53070331; called by muse, mutect2, varscan2
- CCDC62 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754383945, COSV53437513; called by muse, mutect2, varscan2
- CSMD1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.93); catalogued as rs371015364; called by muse, mutect2, varscan2
- DOCK10 | c.5195A>C p.E1732A | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99288303; called by muse, mutect2, varscan2
- GLI4 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs751293783; called by muse, mutect2, varscan2
- H1-2 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781062933, COSV100642241, COSV59192424; called by muse, varscan2
- H1-2 | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 96/162 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59193424; called by muse, varscan2
- HSH2D | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs372833514, COSV99037481; called by muse, mutect2, varscan2
- IGLV4-60 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as rs779430407, COSV66503442; called by muse, mutect2, varscan2
- IL4R | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs749041212, COSV50160433; called by muse, mutect2, varscan2
- MRPL11 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV60599340; called by muse, mutect2
- NDUFAF5 | c.778+1G>T p.X260_splice | Splice Site (SNP) | VAF 63/178 reads (35%) | catalogued as rs779200422; called by muse, mutect2, varscan2
- PCDHB10 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 114/318 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs782184579, COSV53376409, COSV53383976; called by muse, mutect2, varscan2
- SCNN1A | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778199680, COSV57436172; called by muse, mutect2, varscan2
- SOS1 | c.440A>T p.N147I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67676433; called by muse, mutect2, varscan2
- TRPM8 | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100223997; called by muse, mutect2, varscan2
- UGT1A5 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs28946885; called by muse, mutect2, varscan2
- URB2 | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 95/280 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1210244657; called by muse, mutect2, varscan2
- ZNF516 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as rs373443391; called by muse, mutect2, varscan2
- ZNF749 | c.1765T>C p.C589R | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311594078; called by muse, mutect2, varscan2
- C2CD2L | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CBLL2 | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CEP120 | c.2814del p.E939Kfs*7 | Frame Shift Del (DEL) | VAF 136/471 reads (29%) | called by mutect2, pindel, varscan2
- CHD2 | c.2258del p.N753Ifs*3 | Frame Shift Del (DEL) | VAF 65/187 reads (35%) | called by mutect2, pindel, varscan2
- DNER | c.1357A>T p.T453S | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ECD | c.1721C>T p.T574I | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FOXA2 | c.441C>A p.D147E (on ENST00000377115 / NM_153675.3; = p.D153E on NM_021784.5) | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- H2BC4 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 119/283 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HDC | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- HOXA10 | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV3-16 | c.340A>C p.T114P | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KATNIP | c.4756C>T p.Q1586* | Nonsense Mutation (SNP) | VAF 56/132 reads (42%) | called by muse, mutect2, varscan2
- KIAA0319 | c.2270A>G p.D757G | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA0895 | c.1447A>C p.T483P (on ENST00000297063 / NM_001100425.2; = p.T432P on NM_015314.3) | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- LRP1B | c.13423A>C p.T4475P | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.637); called by muse, mutect2
- MST1 | c.1352G>T p.R451M | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- NCAN | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 147/309 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHYHIPL | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- PRDM1 | c.2039T>G p.L680R | Missense Mutation (SNP) | VAF 78/115 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RPS6KA6 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 61/74 reads (82%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTL4 | c.245T>G p.L82W | Missense Mutation (SNP) | VAF 99/128 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SF3B3 | c.2375C>G p.P792R | Missense Mutation (SNP) | VAF 108/299 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SLC4A2 | c.2614G>C p.A872P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, varscan2
- SLITRK1 | c.668T>A p.L223Q | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCP11L1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TICRR | c.4883G>T p.R1628L | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- WDR61 | c.58del p.W20Gfs*21 | Frame Shift Del (DEL) | VAF 94/289 reads (33%) | called by mutect2, pindel, varscan2
- ACTR1A | c.465G>A p.G155= | Silent (SNP) | VAF 70/141 reads (50%) | called by muse, mutect2, varscan2
- CAPN11 | c.1113C>A p.L371= | Silent (SNP) | VAF 114/209 reads (55%) | catalogued as rs928861655; called by muse, mutect2, varscan2
- CNGB3 | c.1029T>C p.S343= | Silent (SNP) | VAF 58/127 reads (46%) | called by muse, mutect2, varscan2
- KCNC3 | c.1899C>T p.I633= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1450164169; called by muse, mutect2, varscan2
- PCDH12 | c.342G>A p.G114= | Silent (SNP) | VAF 172/370 reads (46%) | called by muse, mutect2, varscan2
- PRRG1 | c.57A>T p.P19= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV66158695; called by muse, mutect2
- PTGS2 | c.1788A>G p.L596= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as rs542686634; called by muse, mutect2, varscan2
- ROR2 | c.2007T>C p.G669= | Silent (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- THBS4 | c.2751T>C p.R917= | Silent (SNP) | VAF 79/161 reads (49%) | catalogued as rs765945906; called by muse, mutect2, varscan2
- TXNDC15 | c.798A>G p.L266= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- ASTN2 | c.3355+6405A>G | Intron (SNP) | VAF 26/63 reads (41%) | catalogued as rs1392271708; called by muse, mutect2, varscan2
- BCLAF1P1 | n.776T>G | RNA (SNP) | VAF 51/134 reads (38%) | called by muse, mutect2, varscan2
- BDNF | chr11:27701015 A>C | 5'Flank (SNP) | VAF 143/284 reads (50%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.2671-19A>G | Intron (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- CCND3 | c.198+86A>C | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- CDK12 | c.*1189T>A | 3'UTR (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- COL17A1 | c.1717+182A>G | Intron (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2
- CX3CL1 | c.71-74del | Intron (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel
- DACH1 | c.*329G>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs1396437982; called by muse, mutect2, varscan2
- EBF4 | c.1541-28G>A | Intron (SNP) | VAF 16/27 reads (59%) | catalogued as rs1393391449, COSV61355404; called by muse, mutect2
- ERCC3 | c.2064+108_2064+110del | Intron (DEL) | VAF 23/50 reads (46%) | catalogued as rs1220971608; called by mutect2, pindel, varscan2
- ERI2 | chr16:20806613 G>A | 5'Flank (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2
- FANK1 | c.928-27T>G | Intron (SNP) | VAF 67/212 reads (32%) | called by muse, mutect2, varscan2
- FAT3 | c.*3930G>C | 3'UTR (SNP) | VAF 53/127 reads (42%) | catalogued as rs1428726188; called by muse, mutect2, varscan2
- GABRA2 | c.856+34T>C | Intron (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- GAS2 | c.*916T>C | 3'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.*86A>C | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- HINT1 | c.*239G>A | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- JADE1 | c.1503+2183A>C | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- LAMB1 | c.37+400C>T | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2
- LGI4 | chr19:35135098 del C | 5'Flank (DEL) | VAF 16/44 reads (36%) | catalogued as rs539219272; called by mutect2, varscan2
- LTB | c.163-156A>T | Intron (SNP) | VAF 70/159 reads (44%) | catalogued as rs532177689; called by muse, mutect2, varscan2
- LY6H | c.68-77A>G | Intron (SNP) | VAF 3/31 reads (10%) | catalogued as rs1329782086; called by muse, mutect2
- MCM7 | chr7:100101575 G>C | 5'Flank (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- MEF2D | c.*3583C>G | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- MITF | c.*106A>T | 3'UTR (SNP) | VAF 58/151 reads (38%) | catalogued as rs748243343, COSV58833629; called by muse, mutect2, varscan2
- MX2 | c.1574-144C>T | Intron (SNP) | VAF 39/187 reads (21%) | catalogued as rs879113034; called by muse, mutect2, varscan2
- NEUROD4 | c.*133C>G | 3'UTR (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2
- NFYB | c.*1045A>C | 3'UTR (SNP) | VAF 55/127 reads (43%) | called by muse, mutect2, varscan2
- NR2F2 | c.-381C>A | 5'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- PEX12 | c.*600T>C | 3'UTR (SNP) | VAF 47/129 reads (36%) | called by muse, mutect2, varscan2
- PLCL1 | c.*1272C>A | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- PRLR | c.*1672C>T | 3'UTR (SNP) | VAF 38/106 reads (36%) | catalogued as rs1002728988; called by muse, mutect2, varscan2
- RAB11FIP1 | c.372-427G>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- REPIN1 | c.-161C>T | 5'UTR (SNP) | VAF 33/72 reads (46%) | catalogued as rs1386576584; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2362G>A | RNA (SNP) | VAF 47/70 reads (67%) | catalogued as rs761917304; called by muse, mutect2, varscan2
- RPL27A | c.*3367T>G | 3'UTR (SNP) | VAF 86/175 reads (49%) | called by muse, mutect2, varscan2
- SCAF11 | c.219+620A>G | Intron (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- SDC2 | c.*974del | 3'UTR (DEL) | VAF 43/93 reads (46%) | catalogued as rs1252348297; called by mutect2, varscan2
- SLC51A | c.*46C>A | 3'UTR (SNP) | VAF 26/445 reads (6%) | called by muse, mutect2
- SMN2 | c.*221A>C | 3'UTR (SNP) | VAF 72/90 reads (80%) | called by muse, mutect2, varscan2
- SNORD115-48 | chr15:25269886 A>C | 3'Flank (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- SNTB2 | c.*512T>A | 3'UTR (SNP) | VAF 93/202 reads (46%) | called by muse, mutect2, varscan2
- STK33 | c.-161-729T>C | Intron (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- TASOR | c.2765-58C>T | Intron (SNP) | VAF 52/148 reads (35%) | catalogued as rs1442997782, COSV62927163; called by muse, mutect2, varscan2
- TBC1D15 | c.*803T>C | 3'UTR (SNP) | VAF 46/108 reads (43%) | catalogued as rs1223192893; called by muse, mutect2, varscan2
- TMX2 | c.*390T>G | 3'UTR (SNP) | VAF 121/372 reads (33%) | called by muse, mutect2, varscan2
- TRIM13 | c.*1727A>C | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- TTC26 | c.*729A>C | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- VPS39 | c.1812+80G>C | Intron (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- VWF | c.55+412T>C | Intron (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- ZDHHC2 | c.857+52A>G | Intron (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
